Gene-level copy-number profile of tumor specimen ALCH-ADBW-TTP1-A from ALCHEMIST case ALCH-ADBW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.2 years (19,422 days).
Specimen ALCH-ADBW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 88c78d4a-4e9d-48d3-9938-cfd7a137fe8f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADBW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/686c05f9-ca7f-41ad-95c5-e3890a31556c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 291; copy number 2: 55,164; copy number 3: 2,928; copy number 4: 12; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 266. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
